Somatic mutation profile of tumor specimen 0DV4J6 from CCDI case PBCMFD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.8 years (309 days).
Specimen 0DV4J6: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 944d3ce0-ec1d-4089-b0de-af0d0c7b6630.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV4IS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eef355f9-25cd-4270-b3b0-bf324ab2ed45

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN3 | c.1462G>C p.V488L | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs201458670, COSV54458826; called by muse, mutect2, varscan2
- STXBP4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 171/550 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs200471337; called by muse, mutect2, varscan2
- CDRT15L2 | c.811T>C p.F271L | Missense Mutation (SNP) | VAF 39/537 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.302); called by muse, mutect2
- CTC1 | c.3357G>T p.L1119F | Missense Mutation (SNP) | VAF 27/861 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- MAST3 | c.2104C>A p.H702N | Missense Mutation (SNP) | VAF 146/344 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.038); called by muse, varscan2
- MEIKIN | c.894A>G p.E298= | Silent (SNP) | VAF 11/336 reads (3%) | called by muse, mutect2
- OR10AD1 | c.465C>A p.I155= | Silent (SNP) | VAF 42/478 reads (9%) | catalogued as COSV59613168; called by muse, mutect2
- DISP2 | c.-63_-62insACC | 5'UTR (INS) | VAF 4/52 reads (8%) | catalogued as rs1018445073; called by mutect2, pindel
- FNTA | c.634-47T>C | Intron (SNP) | VAF 50/113 reads (44%) | called by muse, mutect2, varscan2
